Somatic mutation profile of tumor specimen TARGET-40-PARBGW-01A (aliquot TARGET-40-PARBGW-01A-01Y) from TARGET case TARGET-40-PARBGW, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.7 years (4,634 days).
Specimen TARGET-40-PARBGW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98e1696d-61b1-441a-a82a-6bba1c786d73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PARBGW-10A (Blood Derived Normal), aliquot TARGET-40-PARBGW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/817932c5-6caa-43b9-a61a-37523d321d97

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 12, Intron 11, Missense Mutation 9, Silent 3, Splice Site 1, 3'UTR 1, RNA 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.4200dup p.I1401Hfs*8 | Frame Shift Ins (INS) | VAF 14/86 reads (16%) | catalogued as rs398123786; ClinVar: pathogenic; called by mutect2, varscan2
- MYO7A | c.1623dup p.K542Qfs*5 | Frame Shift Ins (INS) | VAF 15/108 reads (14%) | catalogued as rs782077721; ClinVar: pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 11/67 reads (16%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- AKNAD1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100645385; called by muse, mutect2, varscan2
- BCOR | c.2514dup p.K839Qfs*5 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs1394942244; called by pindel, varscan2
- BRINP2 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs777721842; called by muse, varscan2
- FAM117B | c.1144dup p.L382Pfs*6 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs761783143; called by mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 10/70 reads (14%) | catalogued as rs754177800; called by mutect2, varscan2
- KLHL42 | c.1194dup p.C399Vfs*43 | Frame Shift Ins (INS) | VAF 18/144 reads (13%) | catalogued as rs749194179; called by mutect2, varscan2
- KRTAP9-2 | c.198C>A p.C66* | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | catalogued as COSV66646980; called by muse, mutect2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 28/120 reads (23%) | catalogued as rs777328830; called by mutect2, varscan2
- SLC38A7 | c.242dup p.V82Rfs*31 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs755556671; called by pindel, varscan2
- SSH2 | c.2756dup p.E920Rfs*22 | Frame Shift Ins (INS) | VAF 18/160 reads (11%) | catalogued as rs752567808; called by mutect2, varscan2
- SSH2 | c.2498C>T p.S833L | Missense Mutation (SNP) | VAF 200/325 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs144282885; called by muse, mutect2, varscan2
- ARAP1 | c.2497G>A p.E833K (on ENST00000393609 / NM_001040118.2; = p.E588K on NM_015242.4) | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- BSCL2 | c.999G>T p.Q333H | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLIC1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2
- DDX41 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EMG1 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- FOLH1 | c.1597G>T p.G533C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); called by mutect2, varscan2
- KMT2A | c.1660dup p.Q554Pfs*27 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by pindel, varscan2
- RFX6 | c.2499dup p.Y834Lfs*3 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by pindel, varscan2
- SFXN4 | c.732+1G>A p.X244_splice | Splice Site (SNP) | VAF 28/103 reads (27%) | called by muse, varscan2
- SPPL2B | c.369+6G>A | Splice Region (SNP) | VAF 5/27 reads (19%) | called by mutect2, varscan2
- ARAP1 | c.2499G>A p.E833= (on ENST00000393609 / NM_001040118.2; = p.E588= on NM_015242.4) | Silent (SNP) | VAF 28/192 reads (15%) | called by muse, mutect2
- TNFRSF13C | c.462C>T p.T154= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- UNKL | c.1281G>A p.L427= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1299595672; called by muse, mutect2, varscan2
- DCTN1 | c.433-131dup | Intron (INS) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- DDX41 | c.571+114G>A | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- EIF4A2 | c.771+210_771+212del | Intron (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- IGF2BP1 | c.286-12C>G | Intron (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- MIR376A2 | n.5_8dup | RNA (INS) | VAF 8/21 reads (38%) | called by pindel, varscan2
- NXF3 | c.996+16C>T | Intron (SNP) | VAF 46/177 reads (26%) | called by muse, mutect2, varscan2
- PDK2 | c.686-114del | Intron (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- PHACTR1 | c.1727+33dup | Intron (INS) | VAF 18/37 reads (49%) | called by mutect2, varscan2
- PODN | c.457-100G>A | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- ROBO3 | c.*69dup | 3'UTR (INS) | VAF 6/26 reads (23%) | catalogued as rs914699847; called by mutect2, varscan2
- TMC4 | c.1992-51G>A | Intron (SNP) | VAF 4/40 reads (10%) | catalogued as COSV55369404; called by muse, mutect2
- TNFRSF10A | c.1015-36G>A | Intron (SNP) | VAF 18/38 reads (47%) | catalogued as rs201463246; called by muse, mutect2, varscan2
- TRIM6 | c.875-80C>A | Intron (SNP) | VAF 17/207 reads (8%) | called by muse, mutect2
